CCDI case PBBRPW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/57bd3df7-bf80-4492-bcf7-4985e3c6a5ef

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 12.2 years (4,439 days).

Biospecimens (2 samples)
- Sample 0DFF6Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFF72: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
